Somatic mutation profile of tumor specimen TCGA-61-1911-01A (aliquot TCGA-61-1911-01A-01W-0639-09) from TCGA case TCGA-61-1911, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 55.2 years (20,144 days).
Specimen TCGA-61-1911-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fa530ca2-09e1-479b-b08b-d04ea48f7238.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-61-1911-11A (Solid Tissue Normal), aliquot TCGA-61-1911-11A-01W-0640-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5d0eef35-e048-4577-925f-3a519b50eafd

The open-access MAF lists 42 somatic variants for this specimen: 29 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 24, Silent 13, Nonsense Mutation 2, Frame Shift Del 1, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.584T>C p.I195T | Missense Mutation (SNP) | VAF 71/101 reads (70%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs760043106, CM092575, COSV52661172, COSV52664264, COSV52684176, COSV52720899; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS10 | c.448G>A p.V150M | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs146637359; called by muse, mutect2, varscan2
- AP4M1 | c.686G>C p.G229A | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.991); catalogued as COSV57996215; called by mutect2, varscan2
- BDKRB2 | c.701T>A p.L234Q | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV60014681; called by muse, mutect2, varscan2
- CRB1 | c.1888T>C p.F630L | Missense Mutation (SNP) | VAF 19/256 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as COSV100957836, COSV100958101, COSV66328724; called by muse, mutect2
- CSMD1 | c.4487G>T p.S1496I (on ENST00000520002; = p.S1495I on NM_033225.6) | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.997); catalogued as COSV59318486; called by muse, mutect2, varscan2
- EDC4 | c.2792A>T p.D931V | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as COSV100197819; called by muse, mutect2
- GLYR1 | c.406G>T p.V136L | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV58926927; called by muse, mutect2, varscan2
- KDR | c.343T>G p.Y115D | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV55764239; called by muse, mutect2, varscan2
- KIF1B | c.3652C>T p.R1218* (on ENST00000377086 / NM_001365952.1; = p.R1172* on NM_015074.3) | Nonsense Mutation (SNP) | VAF 16/40 reads (40%) | catalogued as COSV55808184; called by muse, mutect2, varscan2
- LIX1L | c.718C>G p.L240V | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63417114; called by muse, mutect2, varscan2
- MMS22L | c.1591T>G p.F531V | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as COSV51520460; called by muse, mutect2, varscan2
- MTPAP | c.632G>A p.C211Y | Missense Mutation (SNP) | VAF 111/414 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs1285110781, COSV53932697; called by muse, mutect2, varscan2
- MYO10 | c.5954G>A p.R1985H | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs369799275; called by muse, mutect2
- OR51B4 | c.236T>G p.V79G | Missense Mutation (SNP) | VAF 52/179 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV66517167; called by muse, mutect2, varscan2
- OR51M1 | c.394T>G p.F132V | Missense Mutation (SNP) | VAF 276/738 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.811); catalogued as COSV100150338, COSV100150423; called by muse, mutect2
- OR5T3 | c.215A>G p.Y72C | Missense Mutation (SNP) | VAF 11/185 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100282974; called by muse, mutect2
- PEG3 | c.3158A>C p.Y1053S | Missense Mutation (SNP) | VAF 68/280 reads (24%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.681); catalogued as COSV55625863, COSV55635862; called by muse, mutect2, varscan2
- PKD1L1 | c.2167G>C p.E723Q | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as COSV56969498, COSV99221636; called by muse, mutect2
- PYROXD2 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.081); catalogued as COSV100282855; called by muse, mutect2
- SHROOM3 | c.5235C>A p.N1745K | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.355); catalogued as COSV56028432; called by muse, mutect2, varscan2
- SI | c.5104T>C p.Y1702H | Missense Mutation (SNP) | VAF 10/261 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV52281609; called by muse, mutect2
- TNN | c.2567G>C p.R856T | Missense Mutation (SNP) | VAF 48/172 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV53425565, COSV53431787; called by muse, mutect2, varscan2
- TOE1 | c.1105C>T p.Q369* | Nonsense Mutation (SNP) | VAF 31/107 reads (29%) | catalogued as COSV59151819; called by muse, mutect2, varscan2
- ZNF229 | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs778772232, COSV52161614; called by muse, mutect2, varscan2
- ZNF25 | c.142+1G>T p.X48_splice | Splice Site (SNP) | VAF 18/119 reads (15%) | catalogued as COSV56922466; called by muse, mutect2, varscan2
- HSPG2 | c.4763G>C p.G1588A | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RPL39L | c.37del p.L13Wfs*17 | Frame Shift Del (DEL) | VAF 124/252 reads (49%) | called by mutect2, pindel, varscan2
- YLPM1 | c.5771_5806del p.G1924_N1935del | In Frame Del (DEL) | VAF 5/41 reads (12%) | called by mutect2, pindel
- ADAMTS9 | c.4143C>T p.G1381= | Silent (SNP) | VAF 71/368 reads (19%) | catalogued as rs1407449998, COSV55780380; called by muse, mutect2, varscan2
- C9orf24 | c.744C>T p.C248= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs1029278156, COSV99898162; called by muse, mutect2
- CASS4 | c.2064C>T p.S688= | Silent (SNP) | VAF 27/64 reads (42%) | catalogued as rs917007163, COSV64386312; called by muse, mutect2, varscan2
- CYP4F12 | c.738G>A p.L246= | Silent (SNP) | VAF 47/224 reads (21%) | catalogued as COSV61173599; called by muse, mutect2, varscan2
- MITF | c.144C>T p.S48= | Silent (SNP) | VAF 39/144 reads (27%) | catalogued as COSV58882733, COSV58883796; called by muse, mutect2, varscan2
- MRPL18 | c.210G>C p.T70= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV58458675; called by muse, mutect2, varscan2
- MTSS1 | c.2118T>G p.T706= | Silent (SNP) | VAF 26/198 reads (13%) | catalogued as rs760685077, COSV52674881; called by muse, mutect2, varscan2
- NLRP11 | c.1620G>A p.T540= | Silent (SNP) | VAF 90/302 reads (30%) | catalogued as rs754117152, COSV64086605; called by muse, mutect2, varscan2
- SLC30A7 | c.126G>A p.L42= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV63017553; called by muse, mutect2, varscan2
- SLC9A2 | c.825C>T p.I275= | Silent (SNP) | VAF 57/181 reads (31%) | catalogued as rs1431914223, COSV52131232; called by muse, mutect2, varscan2
- TRIM35 | c.777A>G p.R259= | Silent (SNP) | VAF 32/118 reads (27%) | catalogued as rs1277520204, COSV100542890, COSV59523297; called by muse, mutect2
- TXNIP | c.738A>G p.T246= | Silent (SNP) | VAF 110/327 reads (34%) | catalogued as rs782724016, COSV65220420; called by muse, mutect2, varscan2
- ZNF674 | c.741C>A p.T247= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as COSV101345071; called by muse, mutect2, varscan2
